Somatic mutation profile of tumor specimen MP2PRT-PATCJG-TMP1-A (aliquot MP2PRT-PATCJG-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PATCJG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,802 days).
Specimen MP2PRT-PATCJG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8c12928-7094-4262-8ec0-dab9dc987181.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCJG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCJG-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3992c436-a3df-4b96-b3b6-536a21418dd0

The open-access MAF lists 21 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 19, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA1 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 233/581 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV66925906; called by muse, mutect2, varscan2
- IGLJ7 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 47/508 reads (9%) | catalogued as rs754728895; called by muse, mutect2
- LOX | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 195/417 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs749796906, COSV99140587; called by muse, mutect2, varscan2
- MYH1 | c.4313G>C p.R1438T | Missense Mutation (SNP) | VAF 123/276 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99874884; called by muse, mutect2, varscan2
- NOTCH3 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 82/804 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs770807625; called by muse, mutect2
- P2RY2 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 171/513 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1441881669, COSV60776944; called by muse, mutect2, varscan2
- PCDHA10 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 76/1200 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.224); catalogued as rs1207727837; called by muse, mutect2
- SH2B3 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 120/247 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746966074; called by muse, mutect2, varscan2
- CPN1 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSN3 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 47/488 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- DDX53 | c.1564A>T p.I522F | Missense Mutation (SNP) | VAF 140/599 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ELOVL1 | c.655T>C p.Y219H | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2
- ITPR2 | c.6678C>G p.I2226M | Missense Mutation (SNP) | VAF 106/255 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MUC2 | c.2531G>T p.C844F | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RIPOR1 | c.2603C>A p.P868H (on ENST00000379312 / NM_001193522.2; = p.P864H on NM_024519.4) | Missense Mutation (SNP) | VAF 21/303 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); called by muse, mutect2
- RUNX1T1 | c.1623C>A p.H541Q (on ENST00000265814 / NM_001198628.1; = p.H514Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/570 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SGSM1 | c.1818G>T p.E606D | Missense Mutation (SNP) | VAF 134/326 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- XK | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 27/796 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2
- ZFP57 | c.1039G>T p.V347L | Missense Mutation (SNP) | VAF 238/616 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- IL22RA1 | c.363C>A p.L121= | Silent (SNP) | VAF 88/262 reads (34%) | catalogued as COSV54627870; called by muse, mutect2
- VPS33B | c.1755G>A p.R585= | Silent (SNP) | VAF 91/285 reads (32%) | catalogued as rs1245881540; called by muse, mutect2, varscan2
